Somatic mutation profile of tumor specimen C3L-01960-01 (aliquot CPT0389730006) from CPTAC case C3L-01960, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary renal cell carcinoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 80.8 years (29,504 days).
Specimen C3L-01960-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b77484ea-fe5e-404b-bf99-e7c3e7db6a0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01960-31 (Blood Derived Normal), aliquot CPT0389760002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c571909-738e-4778-b83c-504563db1837

The open-access MAF lists 80 somatic variants for this specimen: 53 protein-altering or splice-affecting, 16 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 16, 3'UTR 5, Intron 5, In Frame Del 2, Nonsense Mutation 2, Frame Shift Del 2, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6729G>T p.Q2243H | Missense Mutation (SNP) | VAF 100/285 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV64672963; called by muse, mutect2, varscan2
- ARL2BP | c.417A>C p.L139F | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.199); catalogued as rs755190338; called by muse, varscan2
- C5orf58 | c.90A>G p.I30M | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1306976473, COSV69759091; called by muse, mutect2, varscan2
- CCAR1 | c.3205A>G p.I1069V | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.487); catalogued as rs376412284; called by muse, mutect2, varscan2
- CYP20A1 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100619081; called by muse, mutect2, varscan2
- GOLGA4 | c.5154T>A p.Y1718* | Nonsense Mutation (SNP) | VAF 61/273 reads (22%) | catalogued as COSV62712697; called by muse, mutect2, varscan2
- LYN | c.1105C>G p.R369G | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV70206431, COSV70206551; called by muse, mutect2, varscan2
- PAPLN | c.1490C>T p.S497F (on ENST00000554301; = p.S470F on NM_173462.4) | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1163888774; called by muse, mutect2, varscan2
- PRADC1 | c.429C>A p.F143L | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1558555502; called by muse, mutect2, varscan2
- PSMC3IP | c.445G>A p.A149T (on ENST00000393795 / NM_016556.4; = p.A137T on NM_013290.6) | Missense Mutation (SNP) | VAF 111/458 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs760630405; called by muse, mutect2, varscan2
- SCAF11 | c.3736C>G p.P1246A | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1305493135; called by muse, mutect2, varscan2
- TBKBP1 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); catalogued as rs1476066025, COSV64654314; called by muse, mutect2, varscan2
- TCF12 | c.629G>C p.S210T | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.132); catalogued as rs772275976; called by muse, mutect2, varscan2
- TNFRSF10A | c.352A>G p.I118V | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs747581570, COSV55327455; called by muse, mutect2, varscan2
- VTI1A | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs747969091; called by muse, mutect2, varscan2
- ZNF148 | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.384); catalogued as rs370804812; called by muse, varscan2
- ZNF334 | c.1135T>C p.C379R | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as rs768189504; called by muse, mutect2, varscan2
- CAMK2A | c.676A>G p.K226E | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC144A | c.4064C>G p.S1355C | Missense Mutation (SNP) | VAF 56/375 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CELF1 | c.138C>A p.N46K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CISD3 | c.202_204del p.Q68del | In Frame Del (DEL) | VAF 28/172 reads (16%) | called by mutect2, pindel*, varscan2
- COL4A5 | c.4952C>T p.T1651I | Missense Mutation (SNP) | VAF 76/137 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- CR2 | c.1116C>G p.N372K | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDI2 | c.1075C>G p.P359A | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- DDX1 | c.2218T>A p.F740I | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- DNMBP | c.2623G>C p.E875Q | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ENPP1 | c.2192del p.N731Ifs*5 | Frame Shift Del (DEL) | VAF 55/209 reads (26%) | called by mutect2, pindel, varscan2
- ENTPD1 | c.145-4T>A | Splice Region (SNP) | VAF 63/223 reads (28%) | called by muse, mutect2, varscan2
- ETAA1 | c.877T>A p.C293S | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- FEM1C | c.1370G>A p.C457Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2
- FGD6 | c.4019T>A p.L1340* | Nonsense Mutation (SNP) | VAF 38/125 reads (30%) | called by muse, mutect2, varscan2
- GORAB | c.1100T>C p.L367S | Missense Mutation (SNP) | VAF 116/375 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- INPP5F | c.3003_3006del p.E1002Qfs*12 | Frame Shift Del (DEL) | VAF 46/147 reads (31%) | called by mutect2, pindel, varscan2
- LRP2 | c.8427_8429del p.N2810del | In Frame Del (DEL) | VAF 50/199 reads (25%) | called by pindel, varscan2
- MAP1B | c.7309C>A p.H2437N | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PACSIN2 | c.568T>G p.L190V | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PDLIM2 | c.1027T>C p.S343P (on ENST00000397760; = p.S593P on NM_021630.6) | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- RINT1 | c.2018T>A p.I673N | Missense Mutation (SNP) | VAF 79/138 reads (57%) | SIFT tolerated (0.55); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- RNF152 | c.88T>A p.C30S | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RNF19B | c.1843C>T p.H615Y | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- RSKR | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 70/283 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SEPHS2 | c.379A>T p.R127W | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC16A6 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC31A1 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 73/271 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- SMC5 | c.2266C>A p.L756I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.226); called by muse, mutect2
- SPTBN2 | c.4763T>A p.L1588Q | Missense Mutation (SNP) | VAF 116/328 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SYNRG | c.2080T>A p.F694I | Missense Mutation (SNP) | VAF 71/326 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TLR6 | c.347C>A p.S116Y | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- TMEM150C | c.551T>G p.L184R | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- TTLL8 | c.1759G>A p.V587M | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- USP41 | c.284A>G p.Q95R | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZBTB16 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFP36L1 | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ACE2 | c.846A>G p.T282= | Silent (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- ACY3 | c.465C>T p.F155= | Silent (SNP) | VAF 37/156 reads (24%) | called by muse, mutect2, varscan2
- CAPN15 | c.591T>C p.P197= | Silent (SNP) | VAF 132/316 reads (42%) | called by muse, mutect2, varscan2
- CCDC17 | c.1797C>A p.L599= | Silent (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- DMTF1 | c.1239A>G p.Q413= | Silent (SNP) | VAF 56/255 reads (22%) | catalogued as rs375198659; called by muse, mutect2, varscan2
- DOCK2 | c.1371C>T p.G457= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV56968555; called by muse, mutect2, varscan2
- HNRNPDL | c.297C>T p.A99= | Silent (SNP) | VAF 58/273 reads (21%) | catalogued as rs778310020; called by muse, mutect2, varscan2
- HUWE1 | c.1578T>C p.D526= | Silent (SNP) | VAF 42/75 reads (56%) | called by muse, mutect2, varscan2
- INSR | c.1800G>A p.S600= | Silent (SNP) | VAF 72/214 reads (34%) | catalogued as rs139170995; called by muse, mutect2, varscan2
- IRF1 | c.892C>T p.L298= | Silent (SNP) | VAF 58/178 reads (33%) | called by muse, mutect2, varscan2
- KCNC3 | c.615C>T p.P205= | Silent (SNP) | VAF 94/304 reads (31%) | called by muse, mutect2, varscan2
- PDZK1 | c.1116A>G p.V372= | Silent (SNP) | VAF 112/404 reads (28%) | called by muse, mutect2, varscan2
- PHACTR4 | c.633C>A p.T211= (on ENST00000373839 / NM_001350159.2; = p.T221= on NM_023923.4) | Silent (SNP) | VAF 53/185 reads (29%) | catalogued as COSV65783483; called by muse, mutect2, varscan2
- SARM1 | c.1737C>G p.L579= | Silent (SNP) | VAF 60/148 reads (41%) | called by muse, mutect2, varscan2
- SNAP47 | c.75G>A p.S25= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- TNR | c.3204T>A p.I1068= | Silent (SNP) | VAF 27/123 reads (22%) | called by muse, mutect2
- ACSF3 | c.1366+3388C>A | Intron (SNP) | VAF 54/273 reads (20%) | called by muse, mutect2, varscan2
- ADAM10 | c.*25C>A | 3'UTR (SNP) | VAF 122/389 reads (31%) | called by muse, mutect2, varscan2
- ATP6V1G1 | c.-7T>A | 5'UTR (SNP) | VAF 56/162 reads (35%) | called by muse, mutect2, varscan2
- DNAJA4 | c.132+1357A>G | Intron (SNP) | VAF 30/152 reads (20%) | catalogued as rs1280835075; called by muse, mutect2, varscan2
- MTERF4 | c.*1025-311G>A | Intron (SNP) | VAF 26/109 reads (24%) | called by muse, mutect2, varscan2
- PEG10 | c.*344T>C | 3'UTR (SNP) | VAF 111/272 reads (41%) | called by muse, mutect2, varscan2
- SMG7 | c.*1130G>T | 3'UTR (SNP) | VAF 62/246 reads (25%) | called by muse, mutect2, varscan2
- TTC19 | c.*1243T>C | 3'UTR (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- UVSSA | c.*8595T>C | 3'UTR (SNP) | VAF 78/428 reads (18%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.784+284_784+285del | Intron (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- ZNF606 | c.-52+296T>A | Intron (SNP) | VAF 36/148 reads (24%) | called by muse, mutect2, varscan2
